Somatic mutation profile of tumor specimen HTMCP-03-06-02423-01A (aliquot HTMCP-03-06-02423-01A-01D-10409) from CGCI case HTMCP-03-06-02423, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22ac0092-9eaa-457d-9ba4-c997323a6263.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02423-10A (Blood Derived Normal), aliquot HTMCP-03-06-02423-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11997837-5de8-427f-b4f5-6b6e97a67555

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD17B4 | c.77C>T p.P26L (on ENST00000414835 / NM_001199291.3; = p.R23* on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as rs765702241, COSV56338215; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 19/146 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD44 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs533694270, COSV56559966; called by muse, mutect2, varscan2
- DDR2 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1374086542, COSV63370517; called by muse, mutect2
- KCNA1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV66836436; called by muse, mutect2
- PCDHGA5 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.314); catalogued as rs1357530807, COSV54045565; called by muse, mutect2, varscan2
- RYR2 | c.11680G>T p.G3894W | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702759; called by muse, mutect2, varscan2
- ARHGEF12 | c.4129A>T p.S1377C | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ATP13A5 | c.2880del p.P961Hfs*19 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel*, varscan2
- FAM217A | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2
- SCN7A | c.2165A>C p.Y722S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SYNE2 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- TTLL5 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.45); called by muse, mutect2
- UNC80 | c.6209C>A p.P2070H | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF180 | c.1897T>C p.F633L | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- ZNF675 | c.84A>T p.L28F | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALMS1 | c.5178G>A p.L1726= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- AUTS2 | c.3585C>T p.P1195= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- CCDC150 | c.2550G>A p.V850= | Silent (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- WDR33 | c.*3G>A | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as rs750238789; called by mutect2, varscan2
